Somatic mutation profile of tumor specimen TARGET-30-PAUJPC-01A (aliquot TARGET-30-PAUJPC-01A-01D) from TARGET case TARGET-30-PAUJPC, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Abdomen, NOS; Age at diagnosis: 2.1 years (770 days).
Specimen TARGET-30-PAUJPC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 23f7e8d2-421a-4da7-b8f0-8af772e927af.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PAUJPC-10A (Blood Derived Normal), aliquot TARGET-30-PAUJPC-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f437a3b-c7a8-4b22-b327-65fc5972f494

The open-access MAF lists 3 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1, Silent 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPRC | c.637G>T p.V213F | Missense Mutation (SNP) | VAF 21/238 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV61411802; called by muse, mutect2
- COL6A3 | c.7356C>T p.N2452= | Silent (SNP) | VAF 59/133 reads (44%) | catalogued as rs569662223, COSV55088626; called by muse, mutect2, varscan2
- FMN1 | c.*4230G>T | 3'UTR (SNP) | VAF 12/186 reads (6%) | called by muse, mutect2
